WCDT case DTB-089 — Genomic Characterization of Metastatic Castration Resistant Prostate Cancer (WCDT-MCRPC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/b2c85862-acff-4b0e-962f-9d1f898e06a8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; Tissue or organ of origin: Prostate gland; Age at diagnosis: 78.9 years (28,835 days); AJCC clinical M: M1c; AJCC pathologic stage: Stage IV; Last known disease status: Distant met recurrence/progression; Days to last known disease status: 3,958 days (10.8 years); Progression or recurrence: yes; Days to recurrence: 1,090 days (3.0 years); Days to last follow up: 3,958 days (10.8 years).

Follow-up (1 entry)
- Days to follow up: 3,958 days (10.8 years); Disease response: Persistent Distant Metastasis; Progression or recurrence: Yes; Days to progression: 0 days; Days to recurrence: 1,090 days (3.0 years).

Biospecimens (2 samples)
- Sample DTB-089-BL: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Other.
- Sample DTB-089-N: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Biospecimen anatomic site: Blood.
